Somatic mutation profile of tumor specimen TCGA-EE-A2MT-06A (aliquot TCGA-EE-A2MT-06A-11D-A197-08) from TCGA case TCGA-EE-A2MT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.5 years (17,332 days).
Specimen TCGA-EE-A2MT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7966ccc3-2711-406b-a479-e1e22319111d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MT-10A (Blood Derived Normal), aliquot TCGA-EE-A2MT-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94604f01-4e99-4334-a5ff-cab519219ce9

The open-access MAF lists 1,121 somatic variants for this specimen: 732 protein-altering or splice-affecting, 360 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 663, Silent 360, Nonsense Mutation 39, Intron 14, Splice Site 12, Frame Shift Del 10, Splice Region 6, RNA 6, 3'Flank 4, 5'UTR 3, 5'Flank 1, Translation Start Site 1.

Variants (750 of 1,121; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NF1 | c.2530C>T p.L844F | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199474785, CM002379, COSV62197747; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- NF1 | c.5609G>A p.R1870Q (on ENST00000358273 / NM_001042492.3; = p.R1849Q on NM_000267.3) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs786202112, CM1411401, CS000055, CS1311534, CS1311535, COSV62210316; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.5609+1G>A p.X1870_splice (on ENST00000358273 / NM_001042492.3; = p.X1849_splice on NM_000267.3) | Splice Site (SNP) | VAF 20/58 reads (34%) | catalogued as rs1131691117, CS000879, CS072258, CS992457, COSV62194068, COSV62200690, COSV62224640; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POLR3B | c.2774C>T p.P925L | Missense Mutation (SNP) | VAF 56/149 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775141057, COSV57284685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1363C>T p.R455* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | hotspot (GDC flag); catalogued as rs121913302, CM961228, CX1414765, COSV57297545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RB1 | c.1735C>T p.R579* | Nonsense Mutation (SNP) | VAF 19/61 reads (31%) | hotspot (GDC flag); catalogued as rs121913305, CM941206, COSV57294317, COSV99923811; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as COSV100229512; called by muse, mutect2, varscan2
- ABCA12 | c.7448G>A p.G2483E (on ENST00000272895 / NM_173076.3; = p.G2165E on NM_015657.3) | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55975523; called by muse, mutect2, varscan2
- ABCC3 | c.136T>G p.W46G | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV53329287; called by muse, mutect2, varscan2
- ABCC9 | c.3964G>A p.E1322K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV53968621; called by muse, mutect2, varscan2
- ACSL5 | c.1219G>A p.D407N (on ENST00000354273; = p.D463N on NM_016234.3) | Missense Mutation (SNP) | VAF 44/123 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV61133477; called by muse, mutect2, varscan2
- ACSM6 | c.641G>A p.R214K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV58980750; called by muse, mutect2, varscan2
- ACTL8 | c.938G>A p.R313K | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64862694; called by muse, mutect2, varscan2
- ADAM10 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV53049664; called by muse, mutect2, varscan2
- ADAM28 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.426); catalogued as COSV56099066; called by muse, mutect2, varscan2
- ADAM30 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 209/525 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1236043358, COSV101023987; called by muse, mutect2, varscan2
- ADAM30 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 209/526 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV101023988, COSV65561329; called by muse, mutect2, varscan2
- ADAM7 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV51537003; called by muse, mutect2, varscan2
- ADAMTS12 | c.3707T>C p.V1236A | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61279610; called by muse, mutect2, varscan2
- ADAMTS16 | c.2057A>T p.E686V | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.311); catalogued as COSV57007084; called by muse, mutect2, varscan2
- ADAMTS19 | c.2633A>T p.K878I | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV50797848; called by muse, mutect2, varscan2
- ADAMTS2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747875178, COSV51105097; called by muse, mutect2
- ADAMTS20 | c.4086G>A p.W1362* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as COSV67139365; called by muse, mutect2, varscan2
- ADAMTS5 | c.956T>G p.V319G | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV53185349; called by muse, mutect2, varscan2
- ADAMTS6 | c.3061C>T p.R1021C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV58682824; called by muse, mutect2, varscan2
- ADAMTS6 | c.2084A>T p.N695I | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.616); catalogued as COSV66864025; called by muse, mutect2, varscan2
- ADAMTS9 | c.2046G>A p.M682I | Missense Mutation (SNP) | VAF 203/477 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV55787361; called by muse, mutect2, varscan2
- ADCY8 | c.1641G>A p.G547= | Splice Region (SNP) | VAF 66/164 reads (40%) | catalogued as COSV53916065; called by muse, mutect2, varscan2
- ADGRB3 | c.3288-1G>A p.X1096_splice | Splice Site (SNP) | VAF 73/93 reads (78%) | catalogued as COSV53260256, COSV99487096; called by muse, mutect2, varscan2
- ADGRV1 | c.2308G>A p.D770N | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67995391; called by muse, mutect2, varscan2
- ADGRV1 | c.10295C>T p.S3432F | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.398); catalogued as COSV67995398; called by muse, mutect2, varscan2
- ADPRS | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1331569925, COSV52882169; called by muse, mutect2, varscan2
- AIRE | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs1247965967, COSV52397175; called by muse, mutect2, varscan2
- AKAP11 | c.2756C>T p.S919F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV50294547; called by muse, mutect2, varscan2
- AKAP13 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 37/85 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV63469817; called by muse, mutect2, varscan2
- AKAP9 | c.8885C>T p.S2962F (on ENST00000359028; = p.S2938F on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/103 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV62357880; called by muse, mutect2, varscan2
- AL645922.1 | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 224/263 reads (85%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs778844695, COSV54962537; called by muse, mutect2, varscan2
- ALDH1A3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60903304; called by muse, mutect2, varscan2
- ALDH3A1 | c.1116+1G>A p.X372_splice | Splice Site (SNP) | VAF 9/21 reads (43%) | catalogued as COSV56736883; called by muse, mutect2, varscan2
- AMBRA1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 10/20 reads (50%) | catalogued as COSV54062560; called by muse, mutect2, varscan2
- AMER3 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV58470064; called by muse, mutect2, varscan2
- AMPD1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866945097, COSV62418648; called by muse, mutect2, varscan2
- ANK3 | c.12895C>T p.P4299S (on ENST00000280772 / NM_001320874.2; = p.P923S on NM_001149.3) | Missense Mutation (SNP) | VAF 77/172 reads (45%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV55081899; called by muse, mutect2, varscan2
- ANKMY1 | c.2065C>T p.P689S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.269); catalogued as rs751654113, COSV56040921; called by muse, mutect2
- ANKRD20A4P | c.1994C>T p.S665F | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.808); catalogued as COSV100628659; called by mutect2, varscan2
- ANKRD40 | c.192A>T p.L64F | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53334994; called by muse, mutect2, varscan2
- AOX1 | c.278G>A p.G93E | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV65980979; called by muse, mutect2, varscan2
- APOB | c.11915G>A p.G3972E | Missense Mutation (SNP) | VAF 201/531 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV51946074; called by muse, mutect2, varscan2
- APOM | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 111/136 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.049); catalogued as COSV52995199; called by muse, mutect2, varscan2
- ARFIP1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 53/151 reads (35%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1561127602, COSV61886265; called by muse, mutect2, varscan2
- ARGFX | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 42/84 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV57683775; called by muse, mutect2, varscan2
- ARHGAP33 | c.2440A>G p.S814G | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV50164773; called by muse, mutect2, varscan2
- ARHGEF2 | c.2798C>T p.P933L (on ENST00000361247 / NM_001162383.2; = p.P905L on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV58117184; called by muse, mutect2, varscan2
- ARHGEF40 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100070659; called by muse, mutect2, varscan2
- ARL4A | c.214C>T p.H72Y | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as COSV63319628; called by muse, mutect2, varscan2
- ARRDC5 | c.11G>A p.R4K | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs765510781, COSV67788299; called by muse, mutect2, varscan2
- ARVCF | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV54268646, COSV54270117; called by muse, mutect2, varscan2
- ASAH2 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 96/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61484419; called by muse, mutect2, varscan2
- ASB2 | c.389T>C p.L130S | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60114447; called by muse, mutect2, varscan2
- ASCC3 | c.4524G>A p.M1508I | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as COSV64981145; called by muse, mutect2, varscan2
- ASTN2 | c.1133C>T p.S378L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.885); catalogued as rs747307846, COSV57809694; called by muse, mutect2, varscan2
- ASXL1 | c.3523G>A p.E1175K | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.759); catalogued as rs1569336680, COSV60120578; called by muse, mutect2, varscan2
- ATG16L1 | c.1414C>T p.R472C (on ENST00000392017 / NM_030803.7; = p.R453C on NM_017974.4) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61468059; called by muse, mutect2, varscan2
- ATP13A3 | c.892C>T p.P298S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.076); catalogued as COSV55469562; called by muse, mutect2, varscan2
- ATP2B1 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV53812817, COSV99665052; called by muse, mutect2
- ATP6V1C2 | c.173G>A p.G58E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.544); catalogued as COSV99696160; called by muse, mutect2, varscan2
- ATP8A1 | c.200G>A p.R67K | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.93); PolyPhen benign (0.023); catalogued as rs866499854, COSV100047216, COSV52548088; called by muse, mutect2, varscan2
- AXIN1 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs372558302; called by muse, mutect2, varscan2
- BAZ1B | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as COSV59994653; called by muse, mutect2, varscan2
- BCAS1 | c.553C>T p.P185S | Missense Mutation (SNP) | VAF 89/159 reads (56%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.651); catalogued as COSV65083831; called by muse, mutect2, varscan2
- BCO1 | c.1016A>G p.N339S | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV50733976; called by muse, mutect2, varscan2
- BRD4 | c.1945C>T p.P649S | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99651457; called by muse, mutect2, varscan2
- BRD8 | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1212421403, COSV54732282; called by mutect2, varscan2
- BRI3BP | c.419C>T p.S140F | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58297415; called by muse, mutect2, varscan2
- BRINP1 | c.1319G>A p.S440N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.26); PolyPhen benign (0.348); catalogued as COSV56313186; called by muse, mutect2
- BRINP2 | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as rs370977427; called by muse, mutect2, varscan2
- BTBD7 | c.1544C>T p.S515F | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs113550651, COSV58290485; called by muse, mutect2, varscan2
- C12orf42 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.025); catalogued as rs372125844; called by muse, mutect2, varscan2
- C1QL2 | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.658); catalogued as COSV99733371; called by muse, mutect2, varscan2
- C1QL2 | c.574A>T p.T192S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.206); catalogued as COSV99733373; called by muse, mutect2, varscan2
- C6 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867222895, COSV54718556; called by muse, mutect2, varscan2
- CACNA1H | c.2170G>A p.G724S | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100673533, COSV100673729; called by muse, mutect2, varscan2
- CACNB1 | c.1178A>G p.Q393R | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60000253; called by muse, mutect2, varscan2
- CACNB3 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV56400895; called by muse, mutect2, varscan2
- CACTIN | c.224dup p.R76Afs*37 | Frame Shift Ins (INS) | VAF 54/166 reads (33%) | catalogued as rs761795759; called by mutect2, pindel, varscan2
- CAND2 | c.2716G>A p.A906T (on ENST00000456430 / NM_001162499.2; = p.A813T on NM_012298.3) | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV55994619; called by muse, mutect2, varscan2
- CAPN13 | c.1655T>G p.L552R | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV54435428; called by muse, mutect2, varscan2
- CASS4 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs865932743, COSV64388464; called by muse, mutect2, varscan2
- CBL | c.329G>A p.G110E | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.55); catalogued as COSV50663710; called by muse, mutect2, varscan2
- CCAR2 | c.673C>T p.R225W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs769599381, COSV100414952; called by muse, mutect2, varscan2
- CCBE1 | c.919C>T p.P307S | Missense Mutation (SNP) | VAF 93/198 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV67950290; called by muse, mutect2, varscan2
- CCDC102B | c.1279C>T p.Q427* | Nonsense Mutation (SNP) | VAF 4/18 reads (22%) | catalogued as COSV60154411; called by muse, mutect2
- CCDC14 | c.1832C>T p.S611F (on ENST00000488653; = p.S563F on NM_022757.5) | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV59948046; called by muse, mutect2, varscan2
- CCDC141 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs747242213, COSV55382394; called by muse, mutect2, varscan2
- CCDC146 | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.789); catalogued as COSV53554585; called by muse, mutect2, varscan2
- CCDC151 | c.1784C>T p.S595F | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.821); catalogued as COSV100710644; called by muse, mutect2, varscan2
- CCDC173 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV71428661; called by muse, mutect2
- CCDC180 | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV100827337; called by muse, mutect2, varscan2
- CCDC74B | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1452200476, COSV60103719; called by muse, mutect2, varscan2
- CCDC83 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 23/34 reads (68%) | catalogued as COSV54704942; called by muse, mutect2, varscan2
- CCNQ | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 42/47 reads (89%) | catalogued as COSV52345889, COSV99367956; called by muse, mutect2, varscan2
- CCZ1 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.779); catalogued as COSV58075463; called by muse, mutect2, varscan2
- CD163L1 | c.3325G>A p.E1109K | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58024645; called by muse, mutect2, varscan2
- CD300E | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 80/145 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs148103699; called by muse, mutect2, varscan2
- CD55 | c.724C>T p.H242Y | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs780984104, COSV58578135; called by muse, mutect2, varscan2
- CDH16 | c.2022C>A p.Y674* | Nonsense Mutation (SNP) | VAF 38/82 reads (46%) | catalogued as COSV55335113; called by muse, mutect2, varscan2
- CDH6 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 32/59 reads (54%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.632); catalogued as COSV54076372, COSV54078363; called by muse, mutect2, varscan2
- CDH6 | c.1571C>T p.S524L | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.066); catalogued as rs202247793, COSV54065357; called by muse, mutect2, varscan2
- CDK14 | c.994T>C p.F332L (on ENST00000380050 / NM_001287135.2; = p.F314L on NM_012395.3) | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV56052083; called by muse, mutect2, varscan2
- CEACAM20 | c.727G>A p.G243S | Missense Mutation (SNP) | VAF 114/324 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV57603316; called by muse, mutect2, varscan2
- CELSR1 | c.7872C>T p.I2624= | Splice Region (SNP) | VAF 16/40 reads (40%) | catalogued as rs769638723, COSV53084031; called by muse, mutect2
- CELSR1 | c.2485C>T p.Q829* | Nonsense Mutation (SNP) | VAF 30/72 reads (42%) | catalogued as COSV53099803; called by muse, mutect2, varscan2
- CFAP70 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60286889; called by muse, mutect2, varscan2
- CFH | c.2014C>T p.Q672* | Nonsense Mutation (SNP) | VAF 15/84 reads (18%) | catalogued as COSV66405951, COSV66408598; called by muse, mutect2, varscan2
- CHN1 | c.473A>G p.K158R | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV69298676; called by muse, mutect2, varscan2
- CHSY1 | c.1556T>C p.L519P | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.985); catalogued as COSV54256095; called by muse, mutect2, varscan2
- CIART | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1553854690, COSV51746122; called by muse, mutect2, varscan2
- CIT | c.5981C>T p.P1994L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99951039; called by muse, mutect2, varscan2
- CKLF | c.374G>A p.G125E (on ENST00000264001 / NM_016951.4; = p.G40E on NM_016326.3) | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as COSV99862702; called by muse, mutect2, varscan2
- CLCA2 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.265); catalogued as COSV65286875; called by muse, mutect2, varscan2
- CLIP3 | c.367C>T p.H123Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as COSV62112548; called by muse, mutect2, varscan2
- CLNK | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.087); catalogued as COSV57022105; called by muse, mutect2, varscan2
- CLPB | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 70/186 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760523849, COSV53633694; called by muse, mutect2, varscan2
- CLPTM1 | c.973T>A p.S325T | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100493990; called by muse, mutect2, varscan2
- CLRN1 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1553776112, COSV58995522; called by muse, mutect2, varscan2
- CLVS2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV51568979; called by muse, mutect2
- CMYA5 | c.6407C>T p.S2136F | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as rs770432567, COSV71409476; called by muse, mutect2, varscan2
- CNOT6 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56164068; called by muse, mutect2, varscan2
- CNTN6 | c.1711C>T p.H571Y | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63163397; called by muse, mutect2, varscan2
- COL17A1 | c.3454G>A p.G1152R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs762345538, COSV62229390; called by muse, mutect2, varscan2
- COL21A1 | c.2020G>A p.G674R | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55179809; called by muse, mutect2, varscan2
- COL27A1 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0.175); catalogued as rs1388678192, COSV61930795; called by muse, mutect2, varscan2
- COL2A1 | c.3925G>A p.D1309N | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61534457; called by muse, mutect2, varscan2
- COL3A1 | c.416G>A p.G139E | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV58596467; called by muse, mutect2, varscan2
- COL6A2 | c.1817-1G>A p.X606_splice | Splice Site (SNP) | VAF 23/60 reads (38%) | catalogued as COSV56015950; called by muse, mutect2, varscan2
- COL8A1 | c.772G>A p.G258R | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as COSV53742632; called by muse, mutect2, varscan2
- CORO2B | c.886C>T p.R296W | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs1291015819, COSV55949522; called by muse, mutect2, varscan2
- CPA4 | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs1312803690, COSV55985022; called by muse, mutect2, varscan2
- CRB1 | c.4126C>T p.Q1376* | Nonsense Mutation (SNP) | VAF 22/109 reads (20%) | catalogued as COSV66348663; called by muse, mutect2, varscan2
- CRP | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 57/287 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.214); catalogued as COSV54814730; called by muse, mutect2, varscan2
- CRYBB2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1227759128, COSV68005251; called by muse, mutect2, varscan2
- CRYBG1 | c.4282C>G p.R1428G | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749216342, COSV64814571; called by muse, mutect2, varscan2
- CRYBG2 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.859); catalogued as COSV57490259; called by muse, mutect2
- CSMD1 | c.9235C>T p.R3079C (on ENST00000520002; = p.R3078C on NM_033225.6) | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.536); catalogued as rs766431836, COSV59298141; called by muse, mutect2, varscan2
- CSMD1 | c.4183C>T p.P1395S (on ENST00000520002; = p.P1394S on NM_033225.6) | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59382661; called by muse, mutect2
- CSMD3 | c.8401T>G p.S2801A (on ENST00000297405 / NM_001363185.1; = p.S2632A on NM_052900.3) | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (1); PolyPhen possibly damaging (0.525); catalogued as COSV52318028; called by muse, mutect2, varscan2
- CSTF3 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV60614454; called by muse, mutect2
- CSTF3 | c.791T>A p.L264H | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60614463; called by muse, mutect2
- CTIF | c.253-1G>A p.X85_splice | Splice Site (SNP) | VAF 35/88 reads (40%) | catalogued as COSV99838459; called by muse, mutect2, varscan2
- CTIF | c.253A>T p.N85Y | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV99838462; called by muse, mutect2, varscan2
- CTNNBL1 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV63747309; called by muse, varscan2
- CTNND2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58869680; called by muse, mutect2, varscan2
- CTTNBP2 | c.4667T>C p.L1556S | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV50475278; called by muse, mutect2, varscan2
- CXXC1 | c.890G>A p.G297E | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as rs1312308508, COSV53276856; called by muse, mutect2, varscan2
- CYC1 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.058); catalogued as COSV59645076; called by muse, mutect2, varscan2
- CYLC1 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 8/9 reads (89%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as COSV61415873; called by muse, mutect2, varscan2
- CYP4F8 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV57855107; called by muse, mutect2, varscan2
- DDX50 | c.466G>A p.G156R | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.623); catalogued as COSV101007313; called by muse, mutect2, varscan2
- DDX50 | c.467G>A p.G156E | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV101007314; called by muse, mutect2, varscan2
- DDX60L | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV52720259; called by muse, mutect2, varscan2
- DEFB112 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT tolerated (0.6); PolyPhen benign (0.047); catalogued as rs748248344, COSV59183124; called by muse, mutect2, varscan2
- DEFB123 | c.131T>A p.V44D | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV66233747; called by muse, mutect2, varscan2
- DENND3 | c.3165G>A p.M1055I | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1188428035, COSV52806848; called by muse, mutect2, varscan2
- DENND4B | c.3473C>T p.S1158F | Missense Mutation (SNP) | VAF 39/162 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63411946; called by muse, mutect2, varscan2
- DGUOK | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV51205011; called by muse, mutect2, varscan2
- DHX34 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV60898222; called by muse, mutect2, varscan2
- DMXL1 | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as rs373143457, COSV60705358; called by muse, mutect2, varscan2
- DNAH10 | c.4303G>A p.E1435K (on ENST00000409039; = p.E1374K on NM_207437.3) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.201); catalogued as COSV69001564; called by muse, mutect2, varscan2
- DNAH2 | c.6668G>A p.G2223E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746598966, COSV66727256; called by muse, mutect2, varscan2
- DNAH5 | c.10645G>A p.E3549K | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as rs267600360, COSV54210342; called by muse, mutect2, varscan2
- DNAH7 | c.3755C>T p.S1252L | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV56786258; called by muse, mutect2, varscan2
- DNAJC5B | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.254); catalogued as rs1217304685, COSV52539978; called by muse, mutect2, varscan2
- DOCK7 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769508400, COSV52021212; called by muse, mutect2, varscan2
- DPPA2 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.883); catalogued as rs1305691358, COSV101524797; called by muse, mutect2, varscan2
- DPPA3 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as COSV61503044, COSV61503396; called by muse, mutect2, varscan2
- DRC1 | c.1314G>A p.W438* | Nonsense Mutation (SNP) | VAF 20/51 reads (39%) | catalogued as COSV56535469; called by muse, mutect2, varscan2
- DRD5 | c.647A>G p.N216S | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV58580464; called by muse, mutect2, varscan2
- DSC2 | c.547C>T p.R183W | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.806); catalogued as rs368082152; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- DSCAM | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT tolerated (0.17); PolyPhen benign (0.433); catalogued as COSV68036089; called by muse, mutect2, varscan2
- DSG4 | c.3076C>T p.R1026* | Nonsense Mutation (SNP) | VAF 31/87 reads (36%) | catalogued as rs1417105224, COSV57389189; called by muse, mutect2, varscan2
- DUOX2 | c.1358C>T p.P453L | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV66534649; called by muse, mutect2, varscan2
- DYNC2I2 | c.994G>A p.E332K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as COSV63989820; called by muse, mutect2, varscan2
- DYSF | c.6033G>A p.M2011I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV50583295; called by muse, mutect2, varscan2
- E2F1 | c.565C>T p.Q189* | Nonsense Mutation (SNP) | VAF 37/84 reads (44%) | catalogued as COSV58536254; called by muse, mutect2, varscan2
- EBF3 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); catalogued as COSV62473200; called by muse, mutect2, varscan2
- EBI3 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV99696165; called by muse, mutect2
- EDC4 | c.3083C>T p.S1028F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV59303930; called by muse, mutect2, varscan2
- EGF | c.2704G>A p.G902S | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.71); catalogued as COSV54484767; called by muse, mutect2, varscan2
- ELOA2 | c.2258G>A p.R753Q | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55308508; called by muse, mutect2, varscan2
- EML5 | c.4141C>T p.H1381Y (on ENST00000380664; = p.H1389Y on NM_183387.3) | Missense Mutation (SNP) | VAF 43/115 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV61351909; called by muse, mutect2, varscan2
- EPG5 | c.7549G>A p.A2517T | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.91); catalogued as COSV56355991; called by muse, mutect2, varscan2
- EPHA6 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 119/279 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67563189, COSV67575954; called by muse, mutect2, varscan2
- EPHB2 | c.115C>T p.P39S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV65866769; called by muse, mutect2, varscan2
- ERC1 | c.1427C>T p.S476F (on ENST00000360905 / NM_178040.4; = p.S448F on NM_178039.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV61699549; called by muse, mutect2, varscan2
- ERC2 | c.688G>T p.D230Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV55606891, COSV55663417; called by muse, mutect2
- ERCC4 | c.2312C>T p.S771F | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV61313992; called by muse, mutect2, varscan2
- ETV1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.07); catalogued as COSV54151214; called by muse, mutect2, varscan2
- EVPL | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs1416678848; called by muse, mutect2
- EXD2 | c.479C>T p.T160I (on ENST00000312994 / NM_001193362.1; = p.T35I on NM_018199.3) | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as COSV57282229; called by muse, mutect2, varscan2
- F13B | c.1399G>A p.E467K | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV66375682; called by muse, mutect2, varscan2
- FAM160B2 | c.889C>T p.L297F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200199022, COSV99249284; called by muse, varscan2
- FAM193A | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61198699; called by muse, mutect2, varscan2
- FAM47A | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT tolerated (0.74); PolyPhen possibly damaging (0.502); catalogued as rs868662067, COSV60493606; called by muse, mutect2, varscan2
- FAM71F2 | c.227C>T p.T76I | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as COSV66352448; called by muse, mutect2, varscan2
- FANCD2OS | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.654); catalogued as COSV55035821, COSV55046435, COSV99810814; called by muse, mutect2, varscan2
- FARSA | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58906023; called by muse, mutect2, varscan2
- FAT2 | c.1580G>A p.R527K | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs774676657, COSV55812365, COSV55829286, COSV99942668; called by muse, mutect2, varscan2
- FBXL3 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.157); catalogued as COSV62919362; called by muse, mutect2, varscan2
- FCN1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 144/279 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV65662909; called by muse, mutect2, varscan2
- FCRL5 | c.2083C>T p.H695Y | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs762961843, COSV62517656; called by muse, mutect2, varscan2
- FEN1 | c.1079C>T p.P360L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57251500; called by muse, mutect2, varscan2
- FERMT1 | c.845C>T p.P282L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV54097368; called by muse, mutect2
- FFAR1 | c.554G>A p.S185N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.365); catalogued as COSV50068399; called by muse, mutect2, varscan2
- FFAR3 | c.847T>C p.F283L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.057); catalogued as COSV59909724; called by mutect2, varscan2
- FGD6 | c.3580C>T p.P1194S | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.053); catalogued as COSV59697133; called by muse, mutect2, varscan2
- FGFR1 | c.1805C>T p.S602F (on ENST00000447712 / NM_023110.3; = p.S600F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58344520; called by muse, mutect2, varscan2
- FHOD1 | c.3131G>A p.R1044Q | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746584932, COSV50758511; called by muse, mutect2, varscan2
- FKBP4 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV50010022; called by muse, mutect2, varscan2
- FLG | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV64249223; called by muse, mutect2, varscan2
- FLG2 | c.6467G>A p.R2156K | Missense Mutation (SNP) | VAF 118/561 reads (21%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.751); catalogued as COSV66173338; called by muse, mutect2, varscan2
- FLNB | c.3485G>A p.G1162E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895463; called by muse, mutect2, varscan2
- FMN2 | c.2953G>A p.G985S | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.456); catalogued as rs139764401; called by muse, varscan2
- FOXB1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68526492; called by muse, mutect2, varscan2
- FOXD4L3 | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.22); catalogued as rs1344352336; called by mutect2, varscan2
- FOXN1 | c.241C>T p.H81Y | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.444); catalogued as COSV56884185; called by muse, mutect2, varscan2
- FOXO1 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.112); catalogued as rs768903432, COSV101092191; called by muse, mutect2, varscan2
- FREM1 | c.5513G>A p.G1838D | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1297537535, COSV66530098; called by muse, mutect2, varscan2
- FRMPD3 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs774585077, COSV99347126; called by muse, varscan2
- FRY | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 60/121 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV66580157; called by muse, mutect2, varscan2
- FRY | c.2111G>A p.G704E | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs1566109360, COSV66580165; called by muse, mutect2, varscan2
- FSHR | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV58634968; called by muse, mutect2, varscan2
- FTSJ3 | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs142875570; called by muse, mutect2, varscan2
- GABRA4 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.391); catalogued as COSV51935151; called by muse, mutect2, varscan2
- GAS7 | c.1318-1G>A p.X440_splice (on ENST00000432992 / NM_201433.2; = p.X300_splice on NM_003644.3) | Splice Site (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100097089, COSV60442548; called by muse, mutect2, varscan2
- GC | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56739885; called by muse, mutect2, varscan2
- GCAT | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs201266387; called by muse, mutect2, varscan2
- GCKR | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.76); PolyPhen benign (0.14); catalogued as rs987416895, COSV53110780, COSV53111004; called by muse, mutect2, varscan2
- GCN1 | c.6769C>T p.P2257S | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56114762; called by muse, mutect2, varscan2
- GCN1 | c.5038G>A p.A1680T | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100326031; called by muse, mutect2, varscan2
- GEMIN5 | c.3425C>T p.S1142F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as COSV53564879; called by muse, mutect2, varscan2
- GIMAP7 | c.595G>A p.A199T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as rs1471247386, COSV100543797; called by muse, mutect2, varscan2
- GJA1 | c.824C>T p.T275I | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as rs1562174474, COSV56999504; called by muse, mutect2, varscan2
- GJA10 | c.320G>A p.R107K | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.823); catalogued as COSV65356263; called by muse, mutect2, varscan2
- GK | c.1006C>T p.R336C (on ENST00000427190 / NM_001205019.2; = p.R330C on NM_000167.6) | Missense Mutation (SNP) | VAF 16/19 reads (84%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV66732482; called by muse, mutect2, varscan2
- GLI2 | c.2246C>T p.S749F (on ENST00000361492 / NM_001374353.1; = p.S766F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.319); catalogued as COSV58034161, COSV58051354; called by muse, mutect2, varscan2
- GML | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs139347831; called by muse, mutect2, varscan2
- GNA15 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as rs867791191, COSV53588242; called by muse, mutect2, varscan2
- GOLGB1 | c.2368C>T p.H790Y | Missense Mutation (SNP) | VAF 62/119 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as rs760520514, COSV61470951; called by muse, mutect2, varscan2
- GP1BA | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 96/191 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56700592; called by muse, mutect2, varscan2
- GPATCH1 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.824); catalogued as COSV50126512; called by muse, mutect2, varscan2
- GPC5 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as rs777802113, COSV65582090; called by muse, mutect2, varscan2
- GRAMD1A | c.1702C>T p.P568S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.262); catalogued as rs1479830872, COSV58765962; called by muse, mutect2, varscan2
- GRAMD1A | c.1703C>T p.P568L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.334); catalogued as COSV100526427; called by mutect2, varscan2
- GRID2 | c.320C>T p.S107F | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV56265887; called by muse, mutect2, varscan2
- GRIN3A | c.1773G>A p.M591I | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs865773972, COSV62458080; called by muse, mutect2, varscan2
- GRM3 | c.1554G>A p.M518I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs371949904; called by muse, mutect2, varscan2
- GRM6 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs140082247; called by muse, mutect2, varscan2
- GRM8 | c.1406G>A p.G469E | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58868215; called by muse, mutect2, varscan2
- HAL | c.1780C>T p.R594C | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925778606, COSV54116740; called by muse, mutect2, varscan2
- HCRTR2 | c.1034G>A p.W345* | Nonsense Mutation (SNP) | VAF 37/176 reads (21%) | catalogued as COSV63799106; called by muse, mutect2, varscan2
- HDAC9 | c.2912C>T p.A971V | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.4); catalogued as COSV67785193; called by muse, mutect2, varscan2
- HDHD3 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as COSV53058211; called by muse, mutect2, varscan2
- HELZ2 | c.397G>A p.G133R | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776295297, COSV64410483; called by muse, mutect2, varscan2
- HERC2 | c.10721C>T p.S3574F | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV55350356; called by muse, mutect2, varscan2
- HERC5 | c.2459T>A p.L820H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52044963; called by muse, mutect2, varscan2
- HMCN1 | c.6442C>T p.P2148S | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs776707287, COSV54895396, COSV54941406; called by muse, mutect2, varscan2
- HMGCL | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1220289416, COSV52527435; called by muse, mutect2, varscan2
- HMGCS2 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 243/684 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs1250760247, COSV101024931; called by muse, mutect2, varscan2
- HMMR | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); catalogued as COSV62375483; called by muse, mutect2, varscan2
- HNRNPK | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1348162749, COSV61088725; called by muse, mutect2, varscan2
- HRH3 | c.1054C>T p.R352W | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs890686938, COSV58050367; called by muse, mutect2, varscan2
- HS3ST4 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs749218404, COSV58830788; called by muse, mutect2, varscan2
- HTR3A | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV55470810; called by muse, mutect2, varscan2
- IFNL3 | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV69830204; called by muse, mutect2, varscan2
- IGHG3 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs752432493; called by muse, mutect2, varscan2
- IHH | c.655G>A p.A219T | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT tolerated (0.77); PolyPhen benign (0.022); catalogued as rs575127642, COSV55394070; called by muse, mutect2, varscan2
- IKZF2 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 59/137 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59584127; called by muse, mutect2, varscan2
- IL17F | c.341A>G p.E114G | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV60235254; called by muse, mutect2, varscan2
- IL18R1 | c.1268G>A p.G423E | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52127320; called by muse, mutect2, varscan2
- IL18R1 | c.1507G>A p.D503N | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.771); catalogued as rs755292641, COSV52127329; called by muse, mutect2, varscan2
- IL31RA | c.656A>G p.N219S | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV51685193; called by muse, mutect2, varscan2
- INTS1 | c.314C>T p.P105L | Missense Mutation (SNP) | VAF 68/159 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.461); catalogued as COSV67179467; called by muse, varscan2
- INTS6L | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.616); catalogued as COSV100878327; called by muse, mutect2, varscan2
- INTS6L | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as COSV66086345; called by muse, mutect2, varscan2
- IQSEC3 | c.3017C>T p.P1006L (on ENST00000538872 / NM_001170738.2; = p.P703L on NM_015232.1) | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV58290924; called by muse, mutect2, varscan2
- ITGA11 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.245); catalogued as COSV59881974; called by muse, mutect2, varscan2
- ITGA6 | c.841C>A p.P281T (on ENST00000442250; = p.P123T on NM_001316306.2) | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs867565337, COSV99906134; called by muse, mutect2, varscan2
- ITGB2 | c.248G>A p.S83N | Missense Mutation (SNP) | VAF 39/106 reads (37%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1368645784, COSV56613939; called by muse, mutect2, varscan2
- ITGBL1 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); catalogued as rs745378521, COSV66008382, COSV66011885; called by muse, mutect2, varscan2
- ITSN2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV61953998; called by muse, mutect2, varscan2
- JCAD | c.650G>A p.G217E | Missense Mutation (SNP) | VAF 59/162 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as rs1289005376, COSV64761663; called by muse, mutect2, varscan2
- KATNIP | c.725T>C p.V242A | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55191746; called by muse, mutect2, varscan2
- KCNH6 | c.2437G>A p.E813K | Missense Mutation (SNP) | VAF 42/61 reads (69%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs201219951, COSV59002810; called by muse, mutect2, varscan2
- KCNIP4 | c.284A>G p.K95R | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV62857439; called by muse, mutect2, varscan2
- KCNQ5 | c.2600C>T p.S867F | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as rs1252164215, COSV59682740; called by muse, mutect2, varscan2
- KCTD11 | c.269A>C p.Y90S (on ENST00000333751 / NM_001363642.1; = p.Y51S on NM_001002914.2) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV99342014; called by muse, mutect2, varscan2
- KCTD6 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); catalogued as COSV57150840; called by muse, mutect2, varscan2
- KIAA1217 | c.5212-2A>C p.X1738_splice | Splice Site (SNP) | VAF 85/191 reads (45%) | catalogued as COSV56823810; called by muse, mutect2, varscan2
- KIF12 | c.1070G>A p.R357Q (on ENST00000640217; = p.R219Q on NM_138424.1) | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as rs746948055, COSV65118249; called by muse, mutect2, varscan2
- KIF20B | c.3011_3012del p.I1004Rfs*13 (on ENST00000371728 / NM_001284259.2; = p.I964Rfs*13 on NM_016195.4) | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | catalogued as rs759603637; called by mutect2, pindel, varscan2
- KIFC3 | c.1051C>T p.Q351* | Nonsense Mutation (SNP) | VAF 21/42 reads (50%) | catalogued as COSV101109381; called by muse, mutect2, varscan2
- KIT | c.2116C>T p.L706F | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55421405; called by muse, mutect2, varscan2
- KLHDC4 | c.899C>T p.S300F | Missense Mutation (SNP) | VAF 32/61 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs746737818, COSV54510583; called by muse, mutect2, varscan2
- KLHL1 | c.2102G>A p.R701K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.019); catalogued as COSV64784063, COSV64787006; called by muse, mutect2, varscan2
- KLHL24 | c.988C>T p.P330S | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.18); catalogued as COSV54428807; called by muse, mutect2, varscan2
- KRT37 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 27/82 reads (33%) | catalogued as COSV56660046; called by muse, mutect2, varscan2
- KRT6A | c.49G>A p.G17S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.123); catalogued as COSV58107860; called by muse, mutect2, varscan2
- KRTAP4-2 | c.44G>A p.C15Y | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV66659171; called by muse, mutect2, varscan2
- L2HGDH | c.1097C>T p.S366F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.767); catalogued as rs1014146268, COSV55560303; called by muse, mutect2, varscan2
- LAMA2 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV70337375, COSV70343666; called by muse, mutect2, varscan2
- LAMA2 | c.5445+2T>A p.X1815_splice | Splice Site (SNP) | VAF 13/18 reads (72%) | catalogued as COSV70355021; called by muse, mutect2, varscan2
- LAMP5 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55717066; called by muse, mutect2, varscan2
- LCE1A | c.211C>T p.H71Y | Missense Mutation (SNP) | VAF 44/88 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV58728020; called by muse, mutect2, varscan2
- LCN9 | c.437G>A p.G146E | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52992516; called by muse, mutect2, varscan2
- LCT | c.4482G>C p.W1494C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV51557445; called by muse, mutect2, varscan2
- LIG3 | c.2116G>A p.G706S | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758686695, COSV52011297, COSV99252275; called by muse, mutect2, varscan2
- LILRB1 | c.808C>T p.P270S (on ENST00000427581; = p.P234S on NM_006669.6) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.856); catalogued as rs780318750, COSV61119013; called by muse, mutect2, varscan2
- LIPH | c.930T>A p.D310E | Missense Mutation (SNP) | VAF 195/502 reads (39%) | SIFT tolerated (0.68); PolyPhen benign (0.026); catalogued as COSV56186250; called by muse, mutect2, varscan2
- LIPI | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.975); catalogued as rs751166636, COSV100753530, COSV60710297; called by muse, mutect2, varscan2
- LMAN1 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV51825860; called by muse, mutect2, varscan2
- LPO | c.1204C>A p.P402T | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51862520; called by mutect2, varscan2
- LRRC25 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100170625; called by muse, mutect2, varscan2
- LRRC27 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV59811846; called by muse, mutect2, varscan2
- LRRC37A | c.4209G>A p.M1403I | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.38); catalogued as COSV100208283; called by muse, mutect2, varscan2
- LRRIQ3 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs866672669, COSV63041491; called by muse, mutect2, varscan2
- LRRK1 | c.3949C>T p.P1317S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52625910; called by muse, mutect2, varscan2
- LTBP1 | c.956G>A p.G319E | Missense Mutation (SNP) | VAF 62/114 reads (54%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV63197924; called by muse, mutect2, varscan2
- LTBP2 | c.2693G>A p.G898E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56206312; called by muse, mutect2, varscan2
- MACC1 | c.2330G>A p.G777E | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV100255143, COSV60546420; called by muse, mutect2, varscan2
- MAGEA10 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV54885935; called by muse, mutect2, varscan2
- MAGEA8 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 62/74 reads (84%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs782441821, COSV54063772; called by muse, mutect2, varscan2
- MAGEE1 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63912077; called by muse, mutect2, varscan2
- MAP3K20 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100919639, COSV64378825; called by muse, mutect2, varscan2
- MAP3K9 | c.1847C>T p.S616F | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.962); catalogued as COSV67122866; called by muse, mutect2, varscan2
- MAPK10 | c.1075G>A p.E359K (on ENST00000359221 / NM_001351625.2; = p.E397K on NM_002753.5) | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV60394138; called by muse, mutect2, varscan2
- MAPK8IP2 | c.2350T>G p.C784G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50509600; called by muse, mutect2, varscan2
- MATN1 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 58/157 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65651426; called by muse, mutect2, varscan2
- MCM3 | c.1864C>T p.P622S (on ENST00000229854 / NM_001366374.2; = p.P612S on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/130 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57717316, COSV57719393; called by muse, varscan2
- MCM3 | c.905C>T p.S302F (on ENST00000229854 / NM_001366374.2; = p.S292F on NM_002388.6 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.693); catalogued as COSV57719400; called by muse, mutect2, varscan2
- MEP1A | c.1391G>A p.G464E | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57920307; called by muse, mutect2, varscan2
- MGA | c.7186C>T p.R2396* (on ENST00000219905 / NM_001164273.1; = p.R2187* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 35/73 reads (48%) | catalogued as COSV54949891; called by muse, mutect2, varscan2
- MGAM | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV72075848; called by muse, mutect2
- MGAT5B | c.1739C>T p.S580F (on ENST00000569840 / NM_001199172.2; = p.S578F on NM_144677.3) | Missense Mutation (SNP) | VAF 111/169 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV56936776; called by muse, mutect2, varscan2
- MKI67 | c.9747T>G p.S3249R | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV64076941; called by muse, mutect2, varscan2
- MLXIPL | c.2281C>T p.R761C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.963); catalogued as rs782130144, COSV57667645; called by muse, mutect2, varscan2
- MMP20 | c.13C>T p.P5S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1452151478, COSV52778266; called by muse, mutect2, varscan2
- MORC1 | c.2500C>T p.P834S | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs377680519, COSV51715467; called by muse, mutect2, varscan2
- MPP2 | c.1264G>A p.G422S (on ENST00000461854 / NM_001278372.2; = p.G398S on NM_005374.5) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99290844; called by muse, mutect2, varscan2
- MROH2B | c.3247G>A p.D1083N | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV68189518; called by muse, mutect2, varscan2
- MSGN1 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV55263879; called by muse, mutect2, varscan2
- MSH4 | c.1217C>T p.P406L | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV54212042; called by muse, mutect2, varscan2
- MSTN | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53622010; called by muse, mutect2, varscan2
- MTIF3 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 28/75 reads (37%) | catalogued as rs1450179112, COSV66950112; called by muse, mutect2, varscan2
- MTMR11 | c.688C>T p.P230S (on ENST00000439741 / NM_001145862.2; = p.P158S on NM_181873.3) | Missense Mutation (SNP) | VAF 94/188 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as rs918373541, COSV63808707; called by muse, mutect2, varscan2
- MTUS1 | c.3088A>G p.K1030E (on ENST00000262102 / NM_001363061.1; = p.K196E on NM_020749.4) | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.547); catalogued as COSV50590038; called by muse, mutect2, varscan2
- MUC13 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60701264; called by muse, mutect2, varscan2
- MUC3A | c.7667G>A p.R2556K | Missense Mutation (SNP) | VAF 102/359 reads (28%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.01); catalogued as COSV60213151; called by muse, mutect2, varscan2
- MUC3A | c.8335C>T p.P2779S | Missense Mutation (SNP) | VAF 59/320 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.012); catalogued as rs1186101061, COSV60224461; called by muse, mutect2, varscan2
- MXRA5 | c.4327C>T p.L1443F | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.77); PolyPhen benign (0.108); catalogued as COSV54250666; called by muse, mutect2, varscan2
- MYCBPAP | c.934G>A p.D312N | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV60411561, COSV60412270; called by muse, mutect2, varscan2
- MYH1 | c.5216C>T p.S1739F | Missense Mutation (SNP) | VAF 50/118 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV56844579; called by muse, mutect2, varscan2
- MYH10 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV52611223; called by muse, mutect2, varscan2
- MYH11 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as COSV55569692; called by muse, mutect2, varscan2
- MYH13 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.034); catalogued as COSV52820217, COSV52842561; called by muse, mutect2, varscan2
- MYH3 | c.3358G>A p.E1120K | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV56869973; called by muse, mutect2, varscan2
- MYH8 | c.5543G>A p.R1848Q | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs376732590; ClinVar: uncertain significance; called by muse, varscan2
- MYO15A | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.654); catalogued as COSV52766036; called by muse, mutect2, varscan2
- MYO16 | c.4897C>T p.P1633S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62761571; called by muse, mutect2, varscan2
- MYO16 | c.5204C>T p.S1735F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.365); catalogued as COSV62761577; called by muse, mutect2, varscan2
- MYO5C | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55912036; called by muse, mutect2, varscan2
- MYOCD | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 91/209 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as rs372928138; called by muse, mutect2, varscan2
- MYOCD | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV58512155; called by muse, mutect2, varscan2
- MYOM3 | c.2995C>T p.H999Y | Missense Mutation (SNP) | VAF 40/78 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.212); catalogued as COSV58401001; called by muse, varscan2
- MYPN | c.1847G>A p.G616D | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.073); catalogued as COSV62739422; called by muse, mutect2, varscan2
- NAA40 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV58162000; called by muse, mutect2, varscan2
- NAP1L2 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 25/32 reads (78%) | catalogued as COSV100999232, COSV65172895; called by muse, mutect2, varscan2
- NAV3 | c.494G>A p.R165K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV57111768; called by muse, mutect2, varscan2
- NAXD | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV59396152; called by muse, mutect2, varscan2
- NBAS | c.7088C>T p.A2363V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760156969, COSV55737640; called by muse, mutect2, varscan2
- NCKAP5L | c.3676C>T p.P1226S | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.341); catalogued as COSV100258500, COSV100259256; called by muse, mutect2, varscan2
- NCOA2 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.022); catalogued as rs1379336977, COSV71764997; called by muse, mutect2, varscan2
- NEB | c.7582G>A p.D2528N | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs369496057, COSV50836524; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEBL | c.1117-1G>A p.X373_splice | Splice Site (SNP) | VAF 17/36 reads (47%) | catalogued as COSV65805855; called by muse, mutect2, varscan2
- NEO1 | c.1109C>T p.P370L | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56078204; called by muse, mutect2, varscan2
- NETO1 | c.1324G>A p.G442S | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.459); catalogued as rs780303817, COSV55015379; called by muse, mutect2, varscan2
- NKAPL | c.907G>A p.G303S | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1157580961, COSV59199298; called by muse, mutect2, varscan2
- NKD1 | c.893A>C p.H298P | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV51694692; called by muse, mutect2, varscan2
- NLGN2 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.091); catalogued as rs1396674550, COSV57212079; called by muse, mutect2, varscan2
- NLRP2 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.672); catalogued as COSV54756888; called by muse, mutect2, varscan2
- NLRP3 | c.1655C>T p.P552L | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV60230050; called by muse, mutect2, varscan2
- NME7 | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63170849; called by muse, mutect2, varscan2
- NNMT | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 35/54 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as rs1172766305, COSV55475002; called by muse, mutect2, varscan2
- NOS3 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV52495703; called by muse, mutect2, varscan2
- NPAP1 | c.3131G>A p.G1044E | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.631); catalogued as COSV100276228; called by muse, mutect2, varscan2
- NPAS4 | c.754G>A p.G252R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); catalogued as COSV60652828; called by muse, mutect2, varscan2
- NPC1 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.095); catalogued as COSV52583649; called by muse, mutect2, varscan2
- NPHP4 | c.101T>A p.V34D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV65398005; called by muse, mutect2, varscan2
- NR1H4 | c.976G>A p.D326N (on ENST00000551379 / NM_001206993.2; = p.D312N on NM_005123.4) | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.582); catalogued as COSV51856837; called by muse, mutect2, varscan2
- NR6A1 | c.877G>A p.E293K (on ENST00000487099 / NM_033334.4; = p.E288K on NM_001489.5) | Missense Mutation (SNP) | VAF 50/106 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.752); catalogued as rs962951813, COSV100748478, COSV60637828; called by muse, mutect2, varscan2
- NRG3 | c.2131G>A p.E711K (on ENST00000404547 / NM_001370084.1; = p.E687K on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs865805361, COSV64575482; called by muse, mutect2, varscan2
- NRXN1 | c.1618T>A p.F540I | Missense Mutation (SNP) | VAF 30/113 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100455099, COSV58493232; called by muse, mutect2, varscan2
- NSMCE3 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54287840; called by muse, mutect2, varscan2
- NTN4 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766077128, COSV59223700; called by muse, mutect2, varscan2
- NTNG1 | c.1082T>G p.I361S | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV53988403; called by muse, mutect2, varscan2
- NUTM1 | c.2961A>T p.E987D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV59219037; called by muse, mutect2, varscan2
- OAS1 | c.225C>A p.D75E | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.524); catalogued as rs142809544; called by muse, mutect2, varscan2
- OBI1 | c.664C>T p.L222F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs747678734, COSV56147419; called by muse, mutect2, varscan2
- OBSCN | c.21118G>A p.G7040S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1432329108, COSV63468568; called by muse, mutect2
- OGDH | c.2962C>T p.R988W | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777896723, COSV56056963; called by muse, mutect2, varscan2
- OR10A3 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.998); catalogued as COSV62459647, COSV62460273; called by muse, mutect2, varscan2
- OR10A6 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 50/112 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV59164598; called by muse, mutect2, varscan2
- OR13C8 | c.269A>T p.K90I | Missense Mutation (SNP) | VAF 66/165 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as COSV58612477; called by muse, mutect2, varscan2
- OR13C9 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); catalogued as COSV99403565; called by muse, mutect2, varscan2
- OR13C9 | c.126T>A p.N42K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99403566; called by muse, mutect2, varscan2
- OR2G2 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs377218645, COSV60739904; called by muse, mutect2, varscan2
- OR2G2 | c.947T>A p.I316N | Missense Mutation (SNP) | VAF 56/89 reads (63%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as COSV60742322; called by muse, mutect2, varscan2
- OR2G6 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as COSV58574243, COSV58575873; called by muse, mutect2, varscan2
- OR2M4 | c.97G>A p.G33S | Missense Mutation (SNP) | VAF 45/235 reads (19%) | SIFT tolerated (0.5); PolyPhen benign (0.022); catalogued as COSV100141535; called by muse, mutect2, varscan2
- OR4A16 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.16); catalogued as COSV100125415, COSV59041745; called by muse, mutect2, varscan2
- OR4C12 | c.43C>T p.L15F | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV100078366, COSV58861107; called by muse, mutect2, varscan2
- OR4D10 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.189); catalogued as rs773272297, COSV73259969; called by muse, mutect2, varscan2
- OR4N2 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60054905; called by muse, mutect2, varscan2
- OR51A4 | c.683G>A p.G228E | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.718); catalogued as rs1163899070, COSV66750073; called by muse, mutect2, varscan2
- OR51A7 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 51/104 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.58); catalogued as rs1014503001, COSV63788834, COSV63788969; called by muse, mutect2, varscan2
- OR51B4 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66517821; called by muse, mutect2, varscan2
- OR51S1 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs142743963; called by muse, mutect2, varscan2
- OR52N2 | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 102/244 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV57677924; called by muse, mutect2, varscan2
- OR5AN1 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58322415; called by muse, mutect2, varscan2
- OR5AU1 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs369017740; called by muse, mutect2, varscan2
- OR5AU1 | c.263A>T p.K88M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); catalogued as COSV100436220; called by muse, mutect2, varscan2
- OR5J2 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 75/161 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs201346211, COSV56623198; called by muse, mutect2, varscan2
- OR5M8 | c.464G>A p.G155D | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV59118243; called by muse, mutect2, varscan2
- OR8B3 | c.698G>A p.G233E | Missense Mutation (SNP) | VAF 70/104 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV63541442; called by muse, varscan2
- PABPC4 | c.940T>C p.F314L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV63293320, COSV63293679; called by muse, mutect2, varscan2
- PAPPA | c.2519C>G p.T840S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60291774; called by muse, mutect2, varscan2
- PASK | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as COSV52160442; called by muse, mutect2, varscan2
- PCDH15 | c.4565G>A p.R1522K (on ENST00000617271 / NM_001142770.3; = p.K1510= on NM_001142769.3) | Missense Mutation (SNP) | VAF 84/233 reads (36%) | PolyPhen benign (0.006); catalogued as COSV64680988; called by muse, mutect2, varscan2
- PCDH15 | c.4295T>C p.V1432A | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV57393514; called by muse, mutect2, varscan2
- PCDH15 | c.2798G>A p.G933E | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs372984970, COSV100228491; called by muse, mutect2, varscan2
- PCDHB15 | c.400C>T p.P134S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.009); catalogued as COSV51424136; called by muse, mutect2, varscan2
- PCDHB6 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 31/80 reads (39%) | catalogued as COSV50709896; called by muse, mutect2, varscan2
- PCDHB8 | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 61/131 reads (47%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.081); catalogued as rs782252678, COSV50753521; called by muse, mutect2, varscan2
- PCDHGA9 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV54006413; called by muse, mutect2, varscan2
- PCED1A | c.1281G>T p.Q427H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV100642954; called by muse, mutect2, varscan2
- PCID2 | c.148T>G p.C50G | Missense Mutation (SNP) | VAF 57/135 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV55815110; called by muse, mutect2, varscan2
- PCK1 | c.196C>T p.L66F | Missense Mutation (SNP) | VAF 71/131 reads (54%) | SIFT tolerated (0.75); PolyPhen benign (0.112); catalogued as COSV60131135; called by muse, mutect2, varscan2
- PCLO | c.4651G>A p.E1551K | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.298); catalogued as rs1390343890, COSV61632542; called by muse, mutect2, varscan2
- PCNX2 | c.5795G>A p.R1932K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.083); catalogued as COSV50892748; called by muse, mutect2, varscan2
- PCSK9 | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 142/342 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56164847; called by muse, mutect2, varscan2
- PDE11A | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs757470455, COSV53708458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDE12 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 25/53 reads (47%) | catalogued as rs537420334, COSV60819409; called by muse, mutect2, varscan2
- PDE1A | c.950G>A p.R317K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.145); catalogued as COSV59536502; called by muse, mutect2, varscan2
- PDGFC | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV56854970; called by muse, mutect2, varscan2
- PDS5A | c.3527C>T p.P1176L | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs776046561, COSV57831282; called by muse, varscan2
- PDS5B | c.3889C>T p.L1297F | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.155); catalogued as COSV59723836, COSV59734515; called by muse, mutect2, varscan2
- PDZRN4 | c.1688G>A p.R563Q (on ENST00000402685 / NM_001164595.2; = p.R305Q on NM_013377.4) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as rs369918672; called by muse, mutect2, varscan2
- PGBD1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 46/59 reads (78%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV52556083; called by muse, mutect2, varscan2
- PIM2 | c.682C>T p.L228F | Missense Mutation (SNP) | VAF 33/36 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55946383; called by muse, mutect2, varscan2
- PITPNM1 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757636712, COSV54161849; called by muse, mutect2, varscan2
- PKD1L1 | c.3656G>A p.G1219E | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56978082; called by muse, mutect2, varscan2
- PKHD1 | c.4346G>A p.G1449D | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as COSV61894752; called by muse, mutect2, varscan2
- PLCB1 | c.2422G>A p.E808K | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.124); catalogued as rs1370024637, COSV62068375; called by muse, mutect2, varscan2
- PLS1 | c.747T>G p.A249= | Splice Region (SNP) | VAF 7/86 reads (8%) | catalogued as COSV61835499; called by muse, mutect2
- PLXNB2 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 31/72 reads (43%) | catalogued as COSV100834329, COSV63783870; called by muse, mutect2, varscan2
- PLXND1 | c.4222G>A p.E1408K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60719387; called by muse, mutect2, varscan2
- PMF1 | c.270G>A p.E90= | Splice Region (SNP) | VAF 66/343 reads (19%) | catalogued as COSV60772380; called by muse, mutect2, varscan2
- PNMT | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.97); catalogued as COSV54094119; called by muse, mutect2, varscan2
- POLQ | c.4165C>T p.H1389Y | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.255); catalogued as COSV51761305; called by muse, mutect2, varscan2
- POR | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs374350596; called by muse, mutect2, varscan2
- PPOX | c.1225C>T p.H409Y | Missense Mutation (SNP) | VAF 86/111 reads (77%) | SIFT tolerated (1); PolyPhen benign (0.163); catalogued as COSV60528057; called by muse, mutect2, varscan2
- PPP2R2A | c.164T>C p.F55S | Missense Mutation (SNP) | VAF 67/144 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60099171; called by muse, mutect2, varscan2
- PRAG1 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as rs763104094, COSV58166842; called by muse, mutect2, varscan2
- PRB4 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 70/470 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.102); catalogued as rs79639556; called by muse, varscan2
- PRDM9 | c.728C>T p.P243L | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57013272; called by muse, mutect2, varscan2
- PREX2 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774302685, COSV55749445; called by muse, mutect2, varscan2
- PRKD2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV52189724; called by muse, mutect2, varscan2
- PRLR | c.1014G>A p.M338I | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV51500691; called by muse, mutect2, varscan2
- PROC | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071940, CM123617, COSV52167068; called by muse, mutect2, varscan2
- PRORP | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51623178; called by muse, mutect2, varscan2
- PROS1 | c.1601C>T p.P534L | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV67777150; called by muse, mutect2, varscan2
- PROX1 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54778175; called by muse, mutect2, varscan2
- PROX2 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.122); catalogued as COSV71520200; called by muse, mutect2, varscan2
- PROX2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as rs1313550309, COSV101507812, COSV71520201; called by muse, mutect2, varscan2
- PRPF31 | c.1435T>C p.Y479H | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58087272; called by muse, mutect2, varscan2
- PRRC2B | c.2560C>T p.P854S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV61936818; called by muse, mutect2, varscan2
- PRSS12 | c.2470G>A p.D824N | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs1298929535, COSV56610380; called by muse, mutect2, varscan2
- PRTG | c.610C>T p.R204C | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs143548115; called by muse, mutect2, varscan2
- PRUNE2 | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1436888306, COSV100943327; called by muse, mutect2, varscan2
- PSMG3 | c.274A>C p.N92H | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); catalogued as COSV52920962; called by muse, mutect2, varscan2
- PTGFR | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66115075; called by muse, mutect2, varscan2
- PTGS1 | c.1297-1G>A p.X433_splice | Splice Site (SNP) | VAF 19/42 reads (45%) | catalogued as rs765211579, COSV56294755; called by muse, mutect2
- PTPN3 | c.1849G>T p.E617* | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as COSV52711042; called by muse, mutect2, varscan2
- PTPRC | c.2002C>T p.P668S | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV61412441; called by muse, mutect2, varscan2
- PTPRG | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.349); catalogued as rs763411756, COSV55637547; called by muse, mutect2, varscan2
- PTPRO | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV55522932; called by muse, mutect2, varscan2
- PTPRU | c.2177A>C p.K726T | Missense Mutation (SNP) | VAF 53/148 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60536531; called by muse, mutect2, varscan2
- PTRH2 | c.100C>T p.R34* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as rs1474279792, COSV52251824; called by muse, mutect2, varscan2
- PYROXD2 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV65331472; called by muse, mutect2, varscan2
- QRICH2 | c.1610C>T p.P537L | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as COSV53157783; called by muse, mutect2, varscan2
- RAB22A | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 30/53 reads (57%) | catalogued as rs766812693, COSV54833721; called by muse, mutect2, varscan2
- RADIL | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as rs764623431, COSV68203178; called by muse, mutect2, varscan2
- RAI1 | c.2750C>T p.P917L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs773799612, COSV55399230; called by muse, mutect2, varscan2
- RALYL | c.782G>A p.G261E | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV72825663; called by muse, mutect2, varscan2
- RANBP17 | c.3197G>A p.R1066K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.589); catalogued as COSV66657075; called by muse, mutect2, varscan2
- RASEF | c.766-1G>A p.X256_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV64588647; called by muse, mutect2, varscan2
- RASGRP1 | c.161G>A p.G54E | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV60367665; called by muse, mutect2, varscan2
- RASSF9 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 71/180 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.415); catalogued as rs573615562, COSV63433135; called by muse, mutect2, varscan2
- RBM27 | c.2251C>T p.R751C | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54592468; called by muse, mutect2, varscan2
- RCN1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 25/30 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50015210; called by muse, mutect2, varscan2
- RCOR1 | c.959C>T p.S320F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51772539, COSV99031474; called by muse, mutect2, varscan2
- RER1 | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56581331; called by muse, mutect2, varscan2
- RESF1 | c.5232T>G p.S1744R | Missense Mutation (SNP) | VAF 50/191 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100440628; called by muse, mutect2, varscan2
- RESF1 | c.5233C>T p.P1745S | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV100440631; called by muse, mutect2, varscan2
- RNF125 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs373764886, CM1412056; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNF157 | c.55T>G p.S19A | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as COSV53948256; called by muse, mutect2
- ROBO1 | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 55/126 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV71970243; called by muse, mutect2, varscan2
- ROPN1L | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.83); PolyPhen benign (0.015); catalogued as rs753154460, COSV56875091; called by muse, mutect2, varscan2
- RORC | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100562133; called by muse, mutect2, varscan2
- RPGRIP1 | c.2011G>A p.G671R | Missense Mutation (SNP) | VAF 77/189 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV52848168, COSV52857321; called by muse, mutect2, varscan2
- RPS6KC1 | c.2347C>T p.H783Y | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.04); catalogued as COSV65302855; called by muse, mutect2, varscan2
- RUFY2 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs752429335, COSV56260986; called by muse, mutect2, varscan2
- RXFP1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57056673; called by muse, varscan2
- RYR1 | c.2608C>T p.R870W | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs573876812, COSV62105218; called by muse, mutect2, varscan2
- RYR2 | c.5683C>T p.Q1895* | Nonsense Mutation (SNP) | VAF 49/93 reads (53%) | catalogued as COSV100772152, COSV63708735; called by muse, mutect2, varscan2
- RYR3 | c.5765C>T p.S1922F | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV66801393, COSV66808378; called by muse, mutect2, varscan2
- RYR3 | c.11888C>T p.S3963L (on ENST00000389232; = p.S3964L on NM_001036.6) | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs750201337, COSV101215039, COSV66782274; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SACS | c.2816C>T p.S939F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.017); catalogued as rs747773669, COSV66535662; called by muse, mutect2, varscan2
- SALL1 | c.844T>G p.L282V | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV51764599; called by muse, mutect2, varscan2
- SALL4 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 179/315 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.311); catalogued as COSV53856088; called by muse, mutect2, varscan2
- SBK1 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.27); catalogued as rs140773263; called by muse, mutect2, varscan2
- SCD5 | c.967G>A p.A323T | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV60299241; called by muse, mutect2, varscan2
- SCNN1B | c.425T>G p.F142C | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.552); catalogued as COSV56310085; called by muse, mutect2, varscan2
- SCNN1G | c.533G>A p.R178K | Missense Mutation (SNP) | VAF 79/242 reads (33%) | SIFT tolerated (0.82); PolyPhen benign (0.011); catalogued as COSV55602007; called by muse, mutect2, varscan2
- SCRIB | c.3064T>A p.S1022T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV57593168; called by muse, mutect2, varscan2
- SCRN1 | c.694C>T p.H232Y | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.329); catalogued as COSV54129107; called by muse, mutect2, varscan2
- SCYL2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs775398562, COSV100675317; called by muse, mutect2, varscan2
- SDCCAG8 | c.563C>T p.S188F | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV100654111, COSV59417752; called by muse, mutect2, varscan2
- SDK1 | c.3001A>G p.I1001V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs766593426, COSV67388422; called by muse, mutect2, varscan2
- SDK1 | c.3572G>A p.R1191Q | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.028); catalogued as rs377301442; called by muse, mutect2, varscan2
- SEC14L4 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as rs1460870230, COSV55400984; called by muse, mutect2, varscan2
- SEC14L4 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV55401555; called by muse, mutect2, varscan2
- SEC16A | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51536607; called by muse, mutect2, varscan2
- SELE | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 40/190 reads (21%) | catalogued as rs934875938, COSV100325161; called by muse, mutect2
- SELE | c.689G>A p.W230* | Nonsense Mutation (SNP) | VAF 37/180 reads (21%) | catalogued as COSV100325126; called by muse, mutect2, varscan2
- SENP7 | c.2344G>C p.D782H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58619475; called by muse, mutect2, varscan2
- SERPINB11 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as COSV66957817; called by muse, mutect2, varscan2
- SERPINE3 | c.289T>G p.Y97D | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.239); catalogued as COSV68545869; called by muse, mutect2, varscan2
- SETD7 | c.566C>T p.S189L | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV56801951; called by muse, mutect2, varscan2
- SH3D19 | c.1204C>T p.R402C | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778769400, COSV58794081; called by muse, mutect2, varscan2
- SH3RF2 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 51/126 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63041401; called by muse, varscan2
- SHQ1 | c.1481C>T p.P494L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV57764046; called by muse, mutect2, varscan2
- SIDT1 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV53507264; called by muse, mutect2, varscan2
- SIGLEC11 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs532761547, COSV68567840; called by muse, mutect2, varscan2
- SIGLEC11 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV70222169; called by muse, mutect2, varscan2
- SIGLEC12 | c.643G>A p.D215N (on ENST00000291707 / NM_053003.4; = p.D97N on NM_033329.2) | Missense Mutation (SNP) | VAF 44/111 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.044); catalogued as rs755193112, COSV52465033; called by muse, mutect2, varscan2
- SIGLEC12 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.301); catalogued as rs150618212, COSV52464629; called by muse, mutect2
- SIGLECL1 | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1029617725, COSV57064098; called by muse, mutect2, varscan2
- SIM1 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 18/24 reads (75%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as COSV53496760; called by muse, mutect2, varscan2
- SIPA1 | c.395C>T p.S132F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63140827; called by muse, mutect2, varscan2
- SIPA1L2 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV53399858; called by muse, mutect2, varscan2
- SIRPD | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs754826201, COSV101065007, COSV67547265; called by muse, mutect2, varscan2
- SKOR1 | c.1204G>A p.A402T | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1473962146, COSV58250045; called by muse, mutect2, varscan2
- SLC10A3 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 41/49 reads (84%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV54837549; called by muse, mutect2, varscan2
- SLC12A5 | c.514T>C p.S172P (on ENST00000454036 / NM_001134771.2; = p.S149P on NM_020708.5) | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV54801932; called by muse, mutect2, varscan2
- SLC17A6 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54133992, COSV54134887; called by muse, mutect2, varscan2
- SLC25A23 | c.895C>T p.P299S | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51197068; called by muse, mutect2, varscan2
- SLC25A32 | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747038599, COSV52568180; called by muse, mutect2, varscan2
- SLC25A40 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs1305352051, COSV62021699; called by muse, mutect2, varscan2
- SLC26A7 | c.285G>A p.M95I | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV52603407; called by muse, mutect2, varscan2
- SLC2A10 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 54/117 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63716035; called by muse, mutect2, varscan2
- SLC2A14 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 79/220 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.285); catalogued as rs1387980135, COSV100534061; called by muse, mutect2, varscan2
- SLC35F4 | c.1465G>A p.E489K (on ENST00000339762 / NM_001352015.2; = p.E453K on NM_001206920.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.021); catalogued as COSV60264354; called by muse, mutect2, varscan2
- SLC38A4 | c.1009C>T p.P337S | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56969060, COSV56971450; called by muse, mutect2, varscan2
- SLC4A4 | c.3142C>T p.P1048S (on ENST00000264485 / NM_001098484.3; = p.P1004S on NM_003759.4) | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.019); catalogued as COSV99142529; called by muse, mutect2, varscan2
- SLC6A16 | c.2152G>A p.E718K | Missense Mutation (SNP) | VAF 68/133 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as rs760036326, COSV60027568; called by muse, mutect2, varscan2
- SLC6A17 | c.2139T>A p.Y713* | Nonsense Mutation (SNP) | VAF 51/91 reads (56%) | catalogued as COSV58996808; called by muse, mutect2, varscan2
- SLCO1B3 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53946391; called by muse, mutect2, varscan2
- SLCO5A1 | c.940G>T p.A314S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV52653668; called by muse, mutect2, varscan2
- SMC3 | c.1981C>T p.R661W | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62420270; called by muse, mutect2, varscan2
- SMYD4 | c.2194C>T p.R732C | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as rs369531054; called by muse, mutect2, varscan2
- SNAP91 | c.1484T>C p.L495P | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52134294; called by muse, varscan2
- SNRNP200 | c.2533G>A p.G845R | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV60494543; called by muse, mutect2, varscan2
- SOAT2 | c.883A>T p.N295Y | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.771); catalogued as rs759703489, COSV56861325; called by muse, mutect2, varscan2
- SOBP | c.1612C>T p.P538S | Missense Mutation (SNP) | VAF 17/21 reads (81%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58002952; called by muse, mutect2, varscan2
- SORT1 | c.926G>A p.G309E | Missense Mutation (SNP) | VAF 168/406 reads (41%) | SIFT tolerated (0.45); PolyPhen benign (0.172); catalogued as rs1444188793, COSV56670099; called by muse, mutect2, varscan2
- SOS2 | c.2897C>T p.T966I | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.087); catalogued as COSV53574397; called by muse, mutect2, varscan2
- SOSTDC1 | c.31C>T p.L11F | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as COSV61049935; called by muse, mutect2, varscan2
- SPATA31D1 | c.4627C>T p.P1543S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV61201396; called by muse, mutect2, varscan2
- SPATA31E1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs886224668, COSV57795226; called by muse, mutect2
- SPEG | c.7072G>A p.E2358K | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV56679657; called by muse, mutect2, varscan2
- SPEN | c.6625C>T p.Q2209* | Nonsense Mutation (SNP) | VAF 21/58 reads (36%) | catalogued as COSV65367441; called by muse, mutect2, varscan2
- SPNS3 | c.402G>A p.R134= | Splice Region (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100336942, COSV61072256; called by muse, mutect2, varscan2
- SPTA1 | c.2230G>A p.D744N | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as COSV100935611, COSV63753538; called by muse, mutect2, varscan2
- SPTA1 | c.1677G>A p.G559= | Splice Region (SNP) | VAF 68/420 reads (16%) | catalogued as COSV63759345, COSV63761347; called by muse, mutect2, varscan2
- SRPX2 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 43/50 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1171192884, COSV65934550; called by muse, mutect2, varscan2
- SSMEM1 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.859); catalogued as COSV52834393; called by muse, mutect2, varscan2
- STAB2 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV66347115; called by muse, mutect2, varscan2
- STAT5A | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.418); catalogued as COSV61808783; called by muse, mutect2, varscan2
- STK26 | c.299A>G p.E100G | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV61231119; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3259G>A p.V1087I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV59138274; called by muse, mutect2, varscan2
- STON2 | c.769G>A p.E257K (on ENST00000649389 / NM_001366849.2; = p.E200K on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50842232; called by muse, mutect2, varscan2
- STRA6 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV60588609; called by muse, mutect2, varscan2
- STRN | c.2261C>T p.S754L | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV55751981; called by muse, mutect2, varscan2
- SUCNR1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 64/144 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV62912831; called by muse, mutect2, varscan2
- SV2A | c.972G>A p.M324I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.241); catalogued as COSV100974980, COSV64965901; called by muse, mutect2, varscan2
- SYNDIG1L | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.135); catalogued as COSV59048474; called by muse, mutect2, varscan2
- SYNE2 | c.11164-1G>A p.X3722_splice | Splice Site (SNP) | VAF 39/84 reads (46%) | catalogued as COSV59970248; called by muse, mutect2, varscan2
- SYNJ2 | c.2311G>A p.E771K | Missense Mutation (SNP) | VAF 34/50 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs951729369, COSV62896069; called by muse, mutect2, varscan2
- TACR3 | c.605T>A p.I202N | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.433); catalogued as COSV59208693; called by muse, mutect2, varscan2
- TAF1A | c.1163G>C p.W388S | Missense Mutation (SNP) | VAF 391/920 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.775); catalogued as COSV61918277, COSV61918458, COSV61919971; called by muse, mutect2, varscan2
- TANC2 | c.5746G>A p.E1916K | Missense Mutation (SNP) | VAF 53/80 reads (66%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV67341581; called by muse, mutect2, varscan2
- TBC1D10C | c.71C>T p.S24F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56705266; called by muse, mutect2, varscan2
- TCN1 | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV57254733; called by muse, mutect2, varscan2
- TDRKH | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 106/255 reads (42%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.991); catalogued as rs1185660062, COSV64316770; called by muse, mutect2, varscan2
- TEDC1 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 10/23 reads (43%) | catalogued as COSV58155705; called by muse, mutect2, varscan2
- TEKT3 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV58629863; called by muse, mutect2, varscan2
- TEX15 | c.2080G>A p.D694N (on ENST00000256246; = p.D1077N on NM_001350162.2) | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.171); catalogued as COSV56353650; called by muse, mutect2, varscan2
- TICRR | c.3938C>T p.T1313I | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as rs887643190, COSV51546935; called by muse, mutect2, varscan2
- TIE1 | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 37/92 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV65251387; called by muse, mutect2
- TIE1 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65251394; called by muse, mutect2, varscan2
- TIGD3 | c.488C>T p.S163F | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.352); catalogued as COSV52891385; called by muse, mutect2, varscan2
- TIGIT | c.304G>A p.D102N | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs146935299; called by muse, mutect2, varscan2
- TKTL2 | c.1252G>A p.G418S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54921339; called by muse, mutect2, varscan2
- TLR4 | c.791G>A p.R264K (on ENST00000355622 / NM_138554.5; = p.R224K on NM_003266.4) | Missense Mutation (SNP) | VAF 53/102 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62924212; called by muse, mutect2, varscan2
- TLR5 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 57/109 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as COSV60560832; called by muse, mutect2, varscan2
- TM4SF20 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58819495; called by muse, mutect2, varscan2
- TM4SF5 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV54495787; called by muse, mutect2, varscan2
- TMEM244 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs557847545, COSV63742965; called by muse, mutect2, varscan2
- TMEM26 | c.236C>T p.S79L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53264372; called by muse, mutect2, varscan2
- TMEM63B | c.1099C>T p.H367Y | Missense Mutation (SNP) | VAF 84/146 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.334); catalogued as COSV52482394; called by muse, mutect2, varscan2
- TOGARAM2 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs573115970, COSV65423924; called by muse, mutect2, varscan2
- TOGARAM2 | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV65421715, COSV65423931; called by muse, mutect2, varscan2
- TOGARAM2 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65423935; called by muse, mutect2, varscan2
- TP53BP2 | c.2012C>T p.S671F (on ENST00000343537 / NM_001031685.3; = p.S542F on NM_005426.2) | Missense Mutation (SNP) | VAF 166/237 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV59069206; called by muse, mutect2, varscan2
- TPTE | c.1288G>A p.D430N (on ENST00000618007 / NM_199261.4; = p.D412N on NM_199259.4) | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs1185130243; called by mutect2, varscan2
- TRAK1 | c.844G>A p.E282K (on ENST00000327628 / NM_001349247.2; = p.E224K on NM_014965.5) | Missense Mutation (SNP) | VAF 40/97 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100409717, COSV58264620; called by muse, mutect2, varscan2
- TRAM1L1 | c.655G>A p.G219R | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV60293361; called by muse, mutect2, varscan2
- TRAPPC9 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 22/56 reads (39%) | catalogued as COSV66897197, COSV66899336; called by muse, varscan2
- TRAT1 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 53/122 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.208); catalogued as COSV55470926; called by muse, mutect2, varscan2
- TRAT1 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.135); catalogued as COSV55470960; called by muse, varscan2
- TRBV5-1 | c.230G>A p.G77E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); catalogued as rs867262850; called by muse, mutect2, varscan2
- TRIM2 | c.190C>T p.R64C (on ENST00000437508; = p.R91C on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100108289, COSV58631100; called by muse, mutect2, varscan2
- TRIM54 | c.212C>T p.S71F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.005); catalogued as rs1254953879, COSV56085544; called by muse, mutect2, varscan2
- TTC21A | c.995C>G p.S332W | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV57186142, COSV57189454; called by muse, mutect2, varscan2
- TTF1 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV57507329; called by muse, mutect2, varscan2
- TTN | c.92477G>A p.G30826E (on ENST00000591111; = p.G23402E on NM_003319.4) | Missense Mutation (SNP) | VAF 13/33 reads (39%) | PolyPhen probably damaging (1); catalogued as COSV59978906; called by muse, mutect2, varscan2
- TTN | c.64476G>A p.M21492I (on ENST00000591111; = p.M14068I on NM_003319.4) | Missense Mutation (SNP) | VAF 93/218 reads (43%) | PolyPhen benign (0.003); catalogued as COSV60347150, COSV60404749; called by muse, mutect2, varscan2
- TTN | c.62339G>T p.G20780V (on ENST00000591111; = p.G13356V on NM_003319.4) | Missense Mutation (SNP) | VAF 62/131 reads (47%) | PolyPhen probably damaging (1); catalogued as COSV100631007, COSV59942139; called by muse, mutect2, varscan2
- TTN | c.62338G>A p.G20780R (on ENST00000591111; = p.G13356R on NM_003319.4) | Missense Mutation (SNP) | VAF 62/133 reads (47%) | PolyPhen probably damaging (1); catalogued as rs371992765; called by muse, mutect2, varscan2
- TTN | c.54572G>A p.R18191K (on ENST00000591111; = p.R10767K on NM_003319.4) | Missense Mutation (SNP) | VAF 118/289 reads (41%) | PolyPhen benign (0.007); catalogued as rs1405596883, COSV60030138; called by muse, mutect2, varscan2
- TTN | c.53437T>G p.S17813A (on ENST00000591111; = p.S10389A on NM_003319.4) | Missense Mutation (SNP) | VAF 45/147 reads (31%) | PolyPhen benign (0.352); catalogued as COSV60347252; called by muse, mutect2, varscan2
- TTN | c.47065G>A p.G15689R (on ENST00000591111; = p.G8265R on NM_003319.4) | Missense Mutation (SNP) | VAF 14/45 reads (31%) | PolyPhen probably damaging (0.92); catalogued as COSV60077958; called by muse, mutect2, varscan2
- TTN | c.38086C>T p.H12696Y (on ENST00000591111; = p.H5272Y on NM_003319.4) | Missense Mutation (SNP) | VAF 44/101 reads (44%) | PolyPhen benign (0); catalogued as COSV60347338; called by muse, mutect2, varscan2
- TTN | c.33244C>T p.P11082S (on ENST00000591111; = p.P10155S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/118 reads (42%) | PolyPhen benign (0.025); catalogued as COSV59938869; called by muse, mutect2, varscan2
- TTN | c.29536G>A p.A9846T (on ENST00000591111; = p.A8919T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/56 reads (38%) | PolyPhen probably damaging (0.998); catalogued as COSV60347388; called by muse, mutect2, varscan2
- TTN | c.24859G>A p.V8287M (on ENST00000591111; = p.V7360M on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | PolyPhen possibly damaging (0.621); catalogued as rs1160730554, COSV60223166; called by muse, mutect2, varscan2
- TTN | c.24544G>A p.G8182R (on ENST00000591111; = p.G7255R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | PolyPhen possibly damaging (0.841); catalogued as COSV60347409; called by muse, mutect2, varscan2
- TTN | c.21241G>A p.E7081K (on ENST00000591111; = p.E6154K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | PolyPhen benign (0.19); catalogued as COSV60176943; called by muse, mutect2, varscan2
- TTN | c.9812C>T p.S3271F (on ENST00000591111; = p.S3225F on NM_003319.4) | Missense Mutation (SNP) | VAF 60/145 reads (41%) | PolyPhen benign (0.001); catalogued as rs867536098, COSV59891245, COSV60211933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TUBB6 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV52317414; called by muse, mutect2, varscan2
- TUBB6 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 77/196 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52313849; called by muse, mutect2, varscan2
- TXNDC16 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV55984041; called by muse, mutect2, varscan2
- UBR4 | c.8846G>A p.G2949E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.994); catalogued as COSV64399291; called by muse, mutect2, varscan2
- UBR4 | c.3359C>T p.S1120F | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.205); catalogued as COSV64399296; called by muse, mutect2, varscan2
- UGT1A7 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 57/145 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1307548052, COSV60851689; called by muse, mutect2, varscan2
- UGT1A7 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT tolerated (0.67); PolyPhen benign (0.189); catalogued as COSV60851697; called by muse, mutect2, varscan2
- UGT1A9 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (0.947); catalogued as COSV60842376; called by muse, mutect2, varscan2
- UNK | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as COSV53147343; called by muse, mutect2, varscan2
- UPF1 | c.2245C>T p.Q749* (on ENST00000599848 / NM_001297549.2; = p.Q738* on NM_002911.4) | Nonsense Mutation (SNP) | VAF 64/159 reads (40%) | catalogued as COSV53201805; called by muse, mutect2, varscan2
- URB2 | c.3780G>A p.W1260* | Nonsense Mutation (SNP) | VAF 33/174 reads (19%) | catalogued as COSV51046449; called by muse, mutect2, varscan2
- USHBP1 | c.341G>A p.G114E | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99394561; called by muse, mutect2, varscan2
- USP19 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV59738001; called by mutect2, varscan2
- USP29 | c.757G>A p.G253S | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs947345188, COSV104372299, COSV54146679; called by muse, mutect2, varscan2
- USP32 | c.1529G>A p.G510E | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV56277493; called by muse, mutect2, varscan2
- USP7 | c.629A>T p.H210L | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV100784450; called by muse, mutect2, varscan2
- UTP20 | c.6416G>A p.W2139* | Nonsense Mutation (SNP) | VAF 74/171 reads (43%) | catalogued as COSV55385336; called by muse, mutect2, varscan2
- VCAN | c.2813C>T p.S938F | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV54108597, COSV54116633; called by muse, mutect2, varscan2
- VCAN | c.9085T>A p.S3029T | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV54116649; called by muse, mutect2, varscan2
- VIT | c.1900G>A p.E634K (on ENST00000389975 / NM_001177969.1; = p.E649K on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs747748359, COSV64899179; called by muse, mutect2, varscan2
- VKORC1L1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1344770330, COSV62488193; called by muse, mutect2, varscan2
- VPS41 | c.1949G>A p.R650K | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.13); catalogued as COSV59653208; called by muse, mutect2, varscan2
- WDR93 | c.1883C>T p.P628L | Missense Mutation (SNP) | VAF 138/342 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV51532428; called by muse, mutect2, varscan2
- WEE2 | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV66880096; called by muse, mutect2, varscan2
- WFS1 | c.1307C>T p.T436I | Missense Mutation (SNP) | VAF 158/414 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV56991720; called by muse, mutect2, varscan2
- WNT10A | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1183405171, COSV51463681; called by muse, mutect2, varscan2
- WNT3A | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.483); catalogued as COSV52728274, COSV99470195; called by muse, mutect2, varscan2
- XDH | c.3287A>G p.Q1096R | Missense Mutation (SNP) | VAF 59/120 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as COSV65151175; called by muse, mutect2, varscan2
- XIRP2 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV54679872; called by muse, mutect2, varscan2
- XIRP2 | c.3505C>T p.H1169Y (on ENST00000628543; = p.H1344Y on NM_152381.6) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54689957, COSV54733489; called by muse, mutect2, varscan2
- XKR4 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.006); catalogued as COSV59339087; called by muse, mutect2, varscan2
- XXYLT1 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV59988152; called by muse, mutect2, varscan2
- ZBED2 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.195); catalogued as COSV51913043; called by muse, mutect2, varscan2
- ZFP3 | c.1141C>T p.L381F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV59584164; called by muse, mutect2, varscan2
- ZFYVE28 | c.1075T>A p.L359M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV52117422; called by muse, mutect2, varscan2
- ZNF107 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.84); catalogued as rs199803183, COSV61330969, COSV61332029; called by muse, mutect2, varscan2
- ZNF132 | c.496G>A p.G166R | Missense Mutation (SNP) | VAF 47/119 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV54236336; called by muse, mutect2, varscan2
- ZNF160 | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.98); PolyPhen benign (0.02); catalogued as COSV62000961; called by muse, mutect2, varscan2
- ZNF208 | c.3355G>A p.G1119S | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as rs746461940, COSV68112543; called by muse, mutect2, varscan2
- ZNF251 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1439552489, COSV52959226; called by muse, mutect2, varscan2
- ZNF423 | c.1678G>A p.V560M (on ENST00000563137 / NM_001379286.1; = p.V552M on NM_015069.4) | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs750884387, COSV52204557; called by muse, mutect2, varscan2
- ZNF507 | c.136C>T p.H46Y | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as COSV61333335; called by muse, mutect2, varscan2
- ZNF560 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs1211407837, COSV56871733; called by muse, mutect2, varscan2
- ZNF578 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as COSV69737615; called by muse, mutect2, varscan2
- ZNF618 | c.640G>A p.V214M (on ENST00000374126 / NM_001318042.2; = p.V182M on NM_133374.2) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.547); catalogued as rs754511579, COSV55929613; called by muse, mutect2, varscan2
- ZNF644 | c.3950C>T p.S1317L (on ENST00000337393 / NM_201269.3; = p.S95L on NM_016620.3) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV61350370; called by muse, mutect2, varscan2
- ZNF652 | c.868C>T p.H290Y | Missense Mutation (SNP) | VAF 37/138 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV62948766; called by muse, mutect2, varscan2
- ZNF709 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.037); catalogued as COSV67195935; called by muse, varscan2
- ZNF71 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | catalogued as COSV60147721; called by muse, mutect2, varscan2
- ZNF768 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs1304364289, COSV63324369; called by muse, mutect2, varscan2
- ZNF778 | c.2185T>A p.F729I | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60602813; called by muse, mutect2, varscan2
- ZNF786 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs770031879, COSV60277662; called by mutect2, varscan2
- ZNF99 | c.1659G>A p.M553I | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as rs773851802, COSV68056756; called by muse, mutect2, varscan2
- ZNRF3 | c.1499C>T p.P500L (on ENST00000544604 / NM_001206998.2; = p.P400L on NM_032173.3) | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1020453927, COSV60438365; called by muse, mutect2, varscan2
- ZSCAN4 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV56595101; called by muse, mutect2, varscan2
- ASB2 | c.1429T>C p.F477L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, varscan2
- CIT | c.4002_4003delinsT p.P1335Rfs*33 | Frame Shift Del (DEL) | VAF 16/51 reads (31%) | called by pindel, varscan2*
- CSDE1 | c.634_637del p.H212Ifs*8 (on ENST00000358528 / NM_001007553.3; = p.H181Ifs*8 on NM_007158.6) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- EFTUD2 | c.2596del p.S866Pfs*69 | Frame Shift Del (DEL) | VAF 23/59 reads (39%) | called by mutect2, pindel*, varscan2
- ETAA1 | c.1367del p.L456* | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- GDF2 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GPR132 | c.380_383del p.Y127Sfs*105 | Frame Shift Del (DEL) | VAF 61/163 reads (37%) | called by mutect2, pindel, varscan2
- IGHV3OR16-8 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 103/281 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- IGKV2D-30 | c.268A>T p.S90C | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MPZL1 | c.372del p.N124Kfs*32 | Frame Shift Del (DEL) | VAF 13/89 reads (15%) | called by mutect2, pindel, varscan2
- NR1I3 | c.309_321del p.V104Rfs*6 | Frame Shift Del (DEL) | VAF 60/187 reads (32%) | called by mutect2, pindel, varscan2
- PNISR | c.1142C>T p.S381F | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRAMEF5 | c.502C>T p.L168F | Missense Mutation (SNP) | VAF 62/292 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- SARAF | c.854_856delinsTC p.P285Lfs*77 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by pindel, varscan2*
- SSH1 | c.319_321delinsCA p.Y107Qfs*55 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by pindel, varscan2*
- TRAV22 | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- TRAV5 | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- A2ML1 | c.1110C>T p.F370= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV100229509; called by muse, mutect2, varscan2
- ABCC10 | c.2946C>T p.T982= (on ENST00000372530 / NM_001198934.2; = p.T954= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV55093934; called by muse, mutect2, varscan2
- ABCD4 | c.1090C>T p.L364= | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV100084563; called by muse, mutect2
- ABCD4 | c.1089C>T p.I363= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV100084569; called by muse, mutect2
- ACAN | c.5415C>T p.F1805= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV61369399; called by muse, mutect2, varscan2
- ACSM1 | c.621C>T p.S207= | Silent (SNP) | VAF 41/82 reads (50%) | catalogued as COSV54640184; called by muse, mutect2, varscan2
- ACTN1 | c.657C>T p.P219= | Silent (SNP) | VAF 24/65 reads (37%) | catalogued as COSV51997605; called by muse, mutect2, varscan2
- ADAMTS2 | c.390C>T p.L130= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV51105317; called by muse, mutect2, varscan2
- ADAMTS6 | c.2430C>T p.I810= | Silent (SNP) | VAF 27/66 reads (41%) | catalogued as rs781654370, COSV66856727; called by muse, mutect2, varscan2
- ADGRE3 | c.1779C>T p.F593= | Silent (SNP) | VAF 21/49 reads (43%) | catalogued as COSV53734842; called by muse, mutect2, varscan2
- ADGRV1 | c.5931G>A p.G1977= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV67995394; called by muse, mutect2, varscan2
- ALB | c.399C>T p.N133= | Silent (SNP) | VAF 17/37 reads (46%) | catalogued as rs368982595; called by muse, mutect2, varscan2
- ALDH6A1 | c.375G>A p.L125= | Silent (SNP) | VAF 36/73 reads (49%) | catalogued as COSV63247368; called by muse, mutect2, varscan2
- ALG2 | c.739C>T p.L247= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as COSV99445737; called by muse, mutect2, varscan2
- ALG2 | c.738C>T p.A246= | Silent (SNP) | VAF 56/163 reads (34%) | catalogued as COSV53059225; called by muse, mutect2, varscan2
- ALOX15 | c.354G>A p.E118= | Silent (SNP) | VAF 69/187 reads (37%) | catalogued as COSV53400660; called by muse, mutect2, varscan2
- ANXA7 | c.876C>T p.I292= (on ENST00000372919 / NM_001320880.2; = p.I270= on NM_001156.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs139287762; called by muse, mutect2
- APOLD1 | c.462C>T p.I154= (on ENST00000326765 / NM_001130415.2; = p.I123= on NM_030817.3) | Silent (SNP) | VAF 43/81 reads (53%) | catalogued as COSV58734301; called by muse, mutect2, varscan2
371 further variants in this file (0 protein-altering or splice-affecting, 342 silent, 29 other) are not listed here.
